Surgical pathology report (de-identified scan), TCGA case TCGA-61-2009, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2009-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY AND FROZEN SECTION –

METASTATIC POORLY DIFFERENTIATED HIGH GRADE SEROUS PAPILLARY ADENOCARCINOMA.

PART 2: SOFT TISSUE, CUL-DE-SAC TUMOR, EXCISION –

POORLY DIFFERENTIATED HIGH GRADE SEROUS PAPILLARY ADENOCARCINOMA.

PART 3: SOFT TISSUE, CUL-DE-SAC TUMOR, EXCISION –

POORLY DIFFERENTIATED HIGH GRADE SEROUS PAPILLARY ADENOCARCINOMA WITH NECROSIS.

PART 4: OVARY AND FALLOPIAN TUBES, LEFT SALPINGO-OOPHORECTOMY AND FROZEN SECTION –

- A. OVARY WITH POORLY DIFFERENTIATED HIGH GRADE SEROUS PAPILLARY ADENOCARCINOMA (NUCLEAR GRADE 3/3) AND NECROSIS, INVOLVING OVARIAN PARANCHYMA AND SEROSAL ADHESIONS.
- B. BENIGN EPITHELIAL INCLUSIONS AND SEROSAL ADHESIONS.
- C. LEFT FALLOPIAN TUBE WITH METASTATIC ADENOCARCINOMA INVOLVING SEROSAL LYMPHO-VASCULAR SPACES (4A).

PART 5: OVARY AND FALLOPIAN TUBES, RIGHT SALPINGO-OOPHORECTOMY –

- A. OVARY WITH POORLY DIFFERENTIATED HIGH GRADE SEROUS PAPILLARY ADENOCARCINOMA (NUCLEAR GRADE 3/3) AND EXTENSIVE LYMPHOVASCULAR PERMEATION. (see comment)
- B. EPITHELIAL INCLUSIONS AND SEROSAL ADHESIONS.
- C. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYST, NO TUMOR SEEN.

PART 6: PELVIC LYMPH NODES, LEFT, EXCISION –

TWO LYMPH NODES NEGATIVE FOR TUMOR (0/2).

PART 7: SOFT TISSUE, PELVIC TUMOR, EXCISION –

POORLY DIFFERENTIATED HIGH GRADE ADENOCARCINOMA WITH LYMPHOVASCULAR PERMEATION.

PART 8: APPENDIX, APPENDECTOMY –

- A. VERMIFORM APPENDIX WITH METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING PERIAPPENDICIAL ADIPOSE TISSUE, SEROSA AND MUSCULARIS PROPRIA.
- B. FIBROUS OBLITERATION OF TIP.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	Bilateral Salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 10.5 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Omentum
ASSOCIATED OTHER LESION:	Surface epithelial inclusion
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	No
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 2
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Left: 0
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC

Source: NCI Genomic Data Commons file cf87504b-8406-4f44-99c4-b8d51fe6e77f (TCGA-61-2009.39DE8C59-E593-47D3-932D-575A4537B4DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).